Somatic mutation profile of tumor specimen 0DMOXI from CCDI case PBCAUZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 25.8 years (9,415 days).
Specimen 0DMOXI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a95e6569-3a2c-4909-8356-1090df1470d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMOXN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/684780ab-9760-4e16-a0a6-fe60316f69be

The open-access MAF lists 53 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Intron 6, Nonsense Mutation 3, Frame Shift Del 3, 3'UTR 2, Splice Region 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 292/548 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; called by muse, mutect2, varscan2
- CROCC | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 252/670 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.337); catalogued as rs577438145; called by muse, mutect2, varscan2
- GSE1 | c.3469C>G p.R1157G | Missense Mutation (SNP) | VAF 208/782 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.25); catalogued as rs373045100; called by muse, mutect2, varscan2
- PRIM2 | c.1498G>C p.G500R | Missense Mutation (SNP) | VAF 44/941 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); catalogued as COSV67293110; called by muse, mutect2
- PRR23C | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 386/1123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs904602214; called by muse, mutect2, varscan2
- RECQL4 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 181/1076 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1158975362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RECQL4 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 191/810 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs375036010; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF157 | c.1811-7G>A | Splice Region (SNP) | VAF 84/2361 reads (4%) | catalogued as rs761786557; called by muse, mutect2
- ADAM17 | c.1572C>G p.N524K | Missense Mutation (SNP) | VAF 88/851 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADCK5 | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 289/845 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ANKRD17 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 316/1024 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2orf72 | c.815A>G p.D272G | Missense Mutation (SNP) | VAF 170/983 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- C6orf89 | c.1034C>G p.S345* (on ENST00000373685; = p.S352* on NM_152734.4) | Nonsense Mutation (SNP) | VAF 378/1110 reads (34%) | called by muse, mutect2, varscan2
- CPSF1 | c.3935G>A p.W1312* | Nonsense Mutation (SNP) | VAF 193/743 reads (26%) | called by muse, mutect2, varscan2
- CPSF1 | c.3309G>A p.M1103I | Missense Mutation (SNP) | VAF 220/908 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CPSF1 | c.3045G>T p.K1015N | Missense Mutation (SNP) | VAF 219/902 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DAB1 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 338/1285 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DDX39B | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 461/1439 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- EED | c.825_826del p.E276Ifs*3 | Frame Shift Del (DEL) | VAF 204/548 reads (37%) | called by mutect2, pindel, varscan2
- EPB41L5 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 74/1444 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- FCMR | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 62/1544 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.051); called by muse, mutect2
- GALNT3 | c.1298C>A p.A433D | Missense Mutation (SNP) | VAF 441/1515 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HDHD5 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 268/496 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- HEY2 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 64/1108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- MATN2 | c.786del p.C262* | Frame Shift Del (DEL) | VAF 1015/2377 reads (43%) | called by mutect2, pindel, varscan2
- MFSD11 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 196/2902 reads (7%) | called by muse, mutect2
- MILR1 | c.740G>C p.W247S | Missense Mutation (SNP) | VAF 66/1779 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2
- NAB1 | c.637A>C p.S213R | Missense Mutation (SNP) | VAF 39/1386 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2
- NEK4 | c.474C>G p.N158K | Missense Mutation (SNP) | VAF 238/749 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- NFKBIL1 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 302/887 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PCLO | c.12634C>A p.L4212I | Missense Mutation (SNP) | VAF 459/1463 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- PTRH1 | c.174del p.R59Gfs*37 | Frame Shift Del (DEL) | VAF 155/601 reads (26%) | called by mutect2, pindel, varscan2
- RECQL4 | c.2756-3C>T | Splice Region (SNP) | VAF 96/426 reads (23%) | called by muse, mutect2, varscan2
- SERPINB5 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 26/904 reads (3%) | called by muse, mutect2
- SPATA21 | c.971T>C p.L324S | Missense Mutation (SNP) | VAF 40/1116 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- SSH3 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 224/680 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- WDHD1 | c.2917-9_2917del p.X973_splice | Splice Site (DEL) | VAF 54/514 reads (11%) | called by mutect2, pindel
- AKAP14 | c.273T>C p.S91= | Silent (SNP) | VAF 310/707 reads (44%) | called by muse, mutect2, varscan2
- EHF | c.297G>A p.T99= | Silent (SNP) | VAF 302/838 reads (36%) | catalogued as rs769868390, COSV57667774; called by muse, mutect2, varscan2
- KCNC2 | c.1860C>T p.P620= | Silent (SNP) | VAF 396/1221 reads (32%) | called by muse, mutect2, varscan2
- NADK | c.75C>G p.A25= | Silent (SNP) | VAF 149/949 reads (16%) | called by muse, mutect2, varscan2
- NOL9 | c.1797G>A p.Q599= | Silent (SNP) | VAF 340/932 reads (36%) | called by muse, mutect2, varscan2
- PDGFD | c.768A>T p.S256= | Silent (SNP) | VAF 210/728 reads (29%) | called by muse, mutect2, varscan2
- RECQL4 | c.2208C>T p.A736= | Silent (SNP) | VAF 177/843 reads (21%) | called by muse, mutect2, varscan2
- TDRD6 | c.4323G>T p.R1441= | Silent (SNP) | VAF 378/1299 reads (29%) | called by muse, mutect2, varscan2
- ADCK5 | c.*156C>G | 3'UTR (SNP) | VAF 91/420 reads (22%) | called by muse, mutect2, varscan2
- BAIAP2L1 | c.1163+31C>T | Intron (SNP) | VAF 125/423 reads (30%) | catalogued as rs1483868172; called by muse, mutect2, varscan2
- CCDC93 | c.1729-63G>A | Intron (SNP) | VAF 142/453 reads (31%) | called by muse, mutect2, varscan2
- CPSF1 | c.2979+49G>A | Intron (SNP) | VAF 214/849 reads (25%) | called by muse, mutect2
- EGLN2 | c.964-83C>G | Intron (SNP) | VAF 103/344 reads (30%) | called by muse, mutect2, varscan2
- MROH5 | c.81-89A>T | Intron (SNP) | VAF 136/199 reads (68%) | called by muse, mutect2, varscan2
- OXCT2 | c.*41G>A | 3'UTR (SNP) | VAF 80/188 reads (43%) | catalogued as rs1172615202; called by muse, mutect2, varscan2
- PRKACB | c.765+1767C>G | Intron (SNP) | VAF 92/1667 reads (6%) | called by muse, mutect2
